Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DL-01A (Primary Tumor).

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Right palate lesion, biopsy

- Invasive moderately differentiated squamous cell carcinoma

Clinical History:

-year-old male with a palate mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right palate lesion." It holds multiple pale tan soft tissue fragments in aggregate measuring 1.4 x 1.0 x 0.6 cm.

Tissue is taken by Dr. in for the
and the remaining tissue is submitted in block A1,

Addendum

Addendum for inclusion of HPV screening test results.

Addendum Comment

Following case finalization, P16 protein expression was screened by immunohistochemistry, and is negative, with positive external control. High risk HPV was screened by in situ hybridization, and is negative, with positive external controls.

ICD-O-3
Carcinoma squamous cell NOS
Site: Oropharynx NOS C10.9
Palate NOS C05.9
4/5/13

Source: NCI Genomic Data Commons file e880c2a7-e034-4f07-9a7b-6c5ee8f43922 (TCGA-BA-A6DL.95A735F0-7CC4-4B6D-AF78-4566797075F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).